Somatic mutation profile of tumor specimen TCGA-B8-5546-01A (aliquot TCGA-B8-5546-01A-01D-1534-10) from TCGA case TCGA-B8-5546, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 38.6 years (14,113 days).
Specimen TCGA-B8-5546-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ba5aa34-2b01-4041-9768-b91f1b8f7051.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-5546-10A (Blood Derived Normal), aliquot TCGA-B8-5546-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29309701-3afe-4947-8366-300b563337c2

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAST | c.1960C>T p.L654F (on ENST00000341926; = p.L737F on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/257 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs572539750, COSV57091905; called by muse, varscan2
- CD200R1 | c.512C>T p.A171V (on ENST00000471858 / NM_170780.3; = p.A194V on NM_138806.4) | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV55603027; called by muse, mutect2, varscan2
- COL14A1 | c.3209C>A p.T1070N | Missense Mutation (SNP) | VAF 152/337 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs758312974, COSV52870678; called by muse, mutect2, varscan2
- DNAH8 | c.12076T>G p.L4026V | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV59484486; called by muse, mutect2, varscan2
- NEUROD2 | c.292G>A p.G98S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as COSV56911908; called by muse, mutect2, varscan2
- PCLO | c.8019A>C p.E2673D | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV61672427; called by muse, mutect2
- STEAP3 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); catalogued as rs754445970, COSV61530464; called by muse, mutect2, varscan2
- CAST | c.1959T>C p.A653= (on ENST00000341926; = p.A736= on NM_001750.7 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 96/254 reads (38%) | catalogued as COSV57091892; called by muse, varscan2
- TGFBRAP1 | c.786G>A p.A262= | Silent (SNP) | VAF 47/105 reads (45%) | catalogued as rs759936004, COSV51516802; called by muse, mutect2, varscan2
